Gene-level copy-number profile of tumor specimen TCGA-WC-A884-01A from TCGA case TCGA-WC-A884, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 35.2 years (12,840 days).
Specimen TCGA-WC-A884-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.4c5a5e5b-2601-4a2e-8e41-604b78952cd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WC-A884-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/030c2b0e-a2f0-49c6-99f1-f2b63c53e42e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,009; copy number 2: 52,665; copy number 3: 1,616; copy number 4: 880; copy number 5: 601; copy number 6: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WC-A884-01A-11D-A39V-01): tumor purity 0.83, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 637 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,340,998, 14 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene, copy number 5: TRGV5P.
- chr14:22,197,446–22,482,959, 1 gene, copy number 6 (within-gene range 4–6): AC244502.1.
- chr14:22,281,105–22,483,069, 25 genes, copy number 6: TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr17:57,955,965–58,280,935, 21 genes, copy number 5: AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.8, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3, MPO.
- chr17:59,619,689–71,871,750, 317 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:77,198,950–77,920,258, 20 genes, copy number 5: CYCSP40, SEPTIN9-DT, AC068594.1, SEPTIN9, AC111182.1, AC111182.2, MIR4316, Y_RNA, AC111170.3, AC111170.2, AC111170.1, AC021683.3, AC021683.2, AC021683.6, AC021683.1, AC021683.4, AC021683.5, LINC01987, LINC01973, RNU1-80P.
- chr17:78,008,421–78,008,855, 1 gene, copy number 5: AC015804.1.
- chr17:78,991,716–81,034,881, 59 genes, copy number 5: CANT1, C1QTNF1-AS1, C1QTNF1, ENGASE, RBFOX3, AC021534.1, AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31, RPTOR, RPL31P7, AC016245.1, AC016245.2, AC127496.3, AC127496.4, AC127496.1, RPL12P37, CHMP6, AC127496.6, AC127496.7, AC127496.5, AC127496.2, BAIAP2-DT.
- chr17:82,018,702–82,098,294, 10 genes, copy number 6: CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr21:16,862,875–19,303,739, 35 genes, copy number 5: AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1.
- chr21:21,933,315–22,520,058, 9 genes, copy number 5: AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1.
- chr21:26,158,091–29,187,795, 44 genes, copy number 5: AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1.
- chr21:40,010,999–40,847,158, 5 genes, copy number 5 (within-gene range 4–5): DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1.
- chr21:43,529,186–44,711,572, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:46,598,604–46,665,124, 3 genes, copy number 5: S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 1,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
